Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAK7, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAK7-01A (Primary Tumor).

ICD-O-3
Seminoma NOS 9061/3
Site: B Testis NOS C62.9
JW 3/4/14

Concerning

Summary pathology report

Right orchiectomy (undescended testis); seminoma; diameter 2.5 cm; no angio-invasion present; no invasion in rete testis; pagetoid invasion in rete testis; no invasion of tunica albuginea; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchiectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 560034e7-fa52-4ccc-9d4c-8b42d99afbd1 (TCGA-2G-AAK7-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).